Somatic mutation profile of tumor specimen TCGA-FG-6688-01A (aliquot TCGA-FG-6688-01A-11D-1893-08) from TCGA case TCGA-FG-6688, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.5 years (21,745 days).
Specimen TCGA-FG-6688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 137c178b-26df-4cad-a6ca-496f951773e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-6688-10A (Blood Derived Normal), aliquot TCGA-FG-6688-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8da8fe68-c817-4b4e-b0cb-7ab25518ea62

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 39, Silent 16, Nonsense Mutation 6, Frame Shift Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8780T>C p.M2927T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV71292835; called by muse, mutect2
- C2 | c.2066T>A p.F689Y | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100191027; called by muse, mutect2, varscan2
- CENPJ | c.2564G>C p.R855T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67884008; called by muse, mutect2, varscan2
- CERS3 | c.877T>A p.Y293N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as COSV52572993; called by muse, mutect2, varscan2
- CHD4 | c.2327A>G p.N776S (on ENST00000357008 / NM_001363606.2; = p.N789S on NM_001273.5) | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58908170; called by muse, mutect2, varscan2
- CLEC14A | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs761909687, COSV60563142; called by muse, mutect2, varscan2
- CUEDC1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs762829876, COSV64227070; called by muse, mutect2, varscan2
- CYP4F3 | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55412638; called by muse, mutect2
- DSE | c.2449A>C p.K817Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV59066690; called by muse, mutect2, varscan2
- FAM47B | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772125971, COSV61453189; called by muse, mutect2, varscan2
- GRPR | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV66670079; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.539); catalogued as COSV56289593, COSV56298123; called by muse, mutect2, varscan2
- ITIH6 | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.331); catalogued as COSV54493089; called by muse, mutect2, varscan2
- ITIH6 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs747260784, COSV54492091; called by muse, mutect2, varscan2
- LRFN5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs1486862715, COSV53243274; called by muse, mutect2, varscan2
- MAGEE2 | c.1132T>G p.Y378D | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64898310; called by muse, mutect2, varscan2
- MCTP2 | c.1910C>G p.T637S | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV59148663; called by muse, mutect2, varscan2
- MORC1 | c.1240A>T p.K414* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV51727978; called by muse, mutect2, varscan2
- MYO1D | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs369774478; called by muse, mutect2, varscan2
- MYO7B | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV67344938, COSV67350638; called by muse, mutect2, varscan2
- MYOC | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs1351097164, COSV50677257; called by muse, mutect2, varscan2
- NRAP | c.1256G>A p.R419H (on ENST00000359988 / NM_001322945.2; = p.R384H on NM_006175.4) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138124439; called by muse, mutect2, varscan2
- PCDHA1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554117407, COSV65375967; called by muse, mutect2, varscan2
- PCDHA2 | c.2377T>C p.Y793H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV65370213; called by muse, mutect2, varscan2
- PIP4K2C | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs144510690; called by muse, mutect2, varscan2
- PLXNA3 | c.4969C>T p.R1657W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557208958, COSV63755127; called by muse, mutect2, varscan2
- PRSS23 | c.897C>A p.D299E | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV54707398; called by muse, mutect2, varscan2
- RARS1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV51565099; called by muse, mutect2, varscan2
- RTN1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV50740638; called by muse, mutect2, varscan2
- SCN10A | c.3802C>T p.R1268W | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs766044301, COSV71861731; called by muse, mutect2, varscan2
- SETD2 | c.6874C>T p.Q2292* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | catalogued as COSV57432238, COSV57447206; called by muse, mutect2, varscan2
- SLC28A1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs150926643; called by muse, mutect2, varscan2
- SNX29 | c.2152C>G p.P718A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60067980; called by muse, mutect2, varscan2
- SRBD1 | c.2845C>T p.R949* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs573722234, COSV55403847; called by muse, mutect2, varscan2
- TLN1 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs752009662, COSV59210715; called by muse, mutect2, varscan2
- TMEM47 | c.450C>A p.N150K | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52067011; called by muse, mutect2, varscan2
- TRIM60 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as rs368275126; called by muse, mutect2, varscan2
- TSHZ2 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs367984099; called by muse, mutect2, varscan2
- TSPAN33 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768626786, COSV56825539; called by muse, mutect2, varscan2
- TTN | c.22196G>T p.G7399V (on ENST00000591111; = p.G6472V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | PolyPhen possibly damaging (0.879); catalogued as rs751284978, COSV60251377, COSV60265735; called by muse, mutect2, varscan2
- USP6 | c.3337C>T p.R1113* | Nonsense Mutation (SNP) | VAF 45/283 reads (16%) | catalogued as rs377066075; called by muse, mutect2, varscan2
- UTP20 | c.5527C>G p.L1843V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55383344, COSV55385396; called by muse, mutect2, varscan2
- ZNF276 | c.1666T>A p.C556S (on ENST00000443381 / NM_001113525.2; = p.C481S on NM_152287.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57071621; called by muse, mutect2, varscan2
- ZNF691 | c.920G>T p.G307V (on ENST00000372502; = p.G276V on NM_015911.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65289596; called by muse, mutect2, varscan2
- ZNF770 | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV62544781; called by muse, mutect2, varscan2
- AKIP1 | c.518del p.I173Kfs*17 | Frame Shift Del (DEL) | VAF 26/143 reads (18%) | called by mutect2, pindel, varscan2
- F8 | c.3002del p.A1001Vfs*3 | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- PHF21A | c.102_105del p.K34Nfs*13 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- RB1 | c.1647_1650del p.H549Qfs*61 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS15 | c.2028G>A p.G676= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1239256145, COSV54508807; called by muse, mutect2, varscan2
- ADCY7 | c.2766C>G p.P922= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV54269842; called by muse, mutect2, varscan2
- ERC2 | c.2082C>T p.D694= | Silent (SNP) | VAF 39/252 reads (15%) | catalogued as COSV55652859; called by muse, mutect2, varscan2
- FARS2 | c.888A>G p.Q296= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV51173168; called by muse, mutect2, varscan2
- FLNC | c.5097C>T p.D1699= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs1246194093, COSV57953156, COSV57959695; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL1RL1 | c.525C>T p.D175= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs200131845; called by muse, mutect2, varscan2
- IRX6 | c.549C>G p.A183= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV51861766; called by muse, mutect2, varscan2
- KMT2E | c.5319G>A p.P1773= | Silent (SNP) | VAF 46/278 reads (17%) | catalogued as rs369015069; called by muse, mutect2, varscan2
- MUC17 | c.4896A>G p.L1632= | Silent (SNP) | VAF 76/722 reads (11%) | catalogued as rs1216786067, COSV60299451; called by muse, mutect2
- NIPSNAP3A | c.96C>T p.Y32= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs146388542; called by muse, mutect2, varscan2
- PCDHGA4 | c.1836C>T p.S612= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as rs374189449, COSV99533247; called by muse, mutect2, varscan2
- PPP3R1 | c.450T>C p.F150= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV52248821; called by muse, mutect2, varscan2
- PRLR | c.1470G>A p.T490= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs911830967, COSV51499272, COSV51501185; called by muse, mutect2, varscan2
- PTH2R | c.795C>A p.I265= | Silent (SNP) | VAF 44/253 reads (17%) | catalogued as COSV55919295; called by muse, mutect2, varscan2
- TDRD6 | c.30G>A p.P10= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs770066069, COSV60177706; called by muse, mutect2
- TTN | c.100263T>C p.Y33421= (on ENST00000591111; = p.Y25997= on NM_003319.4) | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as rs759152072, COSV60265701; ClinVar: likely benign; called by muse, mutect2, varscan2
